Somatic mutation profile of tumor specimen TCGA-B5-A0K2-01A (aliquot TCGA-B5-A0K2-01A-12W-A10C-09) from TCGA case TCGA-B5-A0K2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 55.0 years (20,080 days).
Specimen TCGA-B5-A0K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b94700e8-9eb8-46ef-8931-5d1e107d26d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K2-10A (Blood Derived Normal), aliquot TCGA-B5-A0K2-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e37faec-00a7-4266-b9ef-76d976927304

The open-access MAF lists 359 somatic variants for this specimen: 286 protein-altering or splice-affecting, 71 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 207, Silent 71, Frame Shift Del 46, Frame Shift Ins 16, Nonsense Mutation 10, In Frame Ins 2, In Frame Del 2, Splice Site 2, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs267607163, CM100191, COSV59248281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.8432dup p.S2812Vfs*3 | Frame Shift Ins (INS) | VAF 72/222 reads (32%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 58/206 reads (28%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- ENG | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.919); catalogued as rs1060501410, CM050046, COSV61228053; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 43/154 reads (28%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 80/284 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- PIK3CA | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 43/152 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55874903, COSV99836298; called by muse, mutect2, varscan2
- PIK3CA | c.1132T>C p.C378R | Missense Mutation (SNP) | VAF 66/241 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.31); PolyPhen possibly damaging (0.715); catalogued as COSV55882697; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 129/298 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/318 reads (12%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB10 | c.815T>A p.I272N | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60622350; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as rs749943218; called by mutect2, varscan2
- ABR | c.912G>T p.K304N (on ENST00000302538 / NM_021962.5; = p.K267N on NM_001092.5) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52148645; called by muse, mutect2, varscan2
- AC004832.3 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs775396821, COSV56742058; called by muse, mutect2, varscan2
- ACSM3 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs554041477, COSV55502192; called by muse, mutect2, varscan2
- ACTN3 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as rs772091427, COSV59749358, COSV59749608; called by muse, mutect2, varscan2
- ADAMTS19 | c.3319A>G p.I1107V | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50765760; called by muse, mutect2, varscan2
- ADGRE1 | c.2204G>A p.G735D | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV51678161; called by muse, mutect2, varscan2
- ALK | c.3836G>T p.R1279M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66577979; called by muse, mutect2, varscan2
- ALPK3 | c.4177G>A p.A1393T | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV51936040; called by muse, mutect2, varscan2
- ANKRD13A | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55677254; called by muse, mutect2, varscan2
- ANKS6 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs370396130; called by muse, mutect2, varscan2
- APOF | c.705del p.P236Lfs*4 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as COSV58477085; called by mutect2, pindel, varscan2
- ARHGEF10L | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs148614735, COSV51434297; called by muse, mutect2, varscan2
- ARR3 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52104695; called by muse, mutect2
- ARSJ | c.1611dup p.K538Qfs*6 | Frame Shift Ins (INS) | VAF 51/266 reads (19%) | catalogued as rs1262094668; called by pindel, varscan2
- ART5 | c.679dup p.H227Pfs*2 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs748137393; called by mutect2, varscan2
- ASPHD1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as COSV58101298; called by muse, mutect2, varscan2
- ATG16L1 | c.1206C>A p.H402Q (on ENST00000392017 / NM_030803.7; = p.H383Q on NM_017974.4) | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV61466768; called by muse, mutect2, varscan2
- AXIN2 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61058886; called by muse, mutect2, varscan2
- BAZ1A | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs750788363, COSV62409920; called by muse, mutect2, varscan2
- BCL9 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1553205031, COSV52347216; called by muse, mutect2, varscan2
- BCL9L | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1235293157; called by muse, mutect2
- BIRC6 | c.5857G>A p.A1953T | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.552); catalogued as COSV70202632; called by muse, mutect2, varscan2
- BYSL | c.1187A>G p.D396G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV57829017; called by muse, mutect2, varscan2
- C1R | c.1519G>T p.G507C (on ENST00000536053 / NM_001354346.2; = p.G493C on NM_001733.7) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73383021; called by muse, mutect2, varscan2
- CACNA2D3 | c.2854C>T p.H952Y | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV55558170; called by muse, mutect2, varscan2
- CAMTA1 | c.4447G>A p.A1483T | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs371421140, COSV57906471; called by muse, mutect2, varscan2
- CCIN | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs150485511; called by muse, mutect2, varscan2
- CCR9 | c.226T>G p.C76G (on ENST00000357632 / NM_031200.3; = p.C64G on NM_006641.4) | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.636); catalogued as rs764365883, COSV62940506; called by muse, mutect2, varscan2
- CD163 | c.1302C>G p.N434K | Missense Mutation (SNP) | VAF 136/397 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.119); catalogued as COSV63134907; called by muse, mutect2, varscan2
- CDH2 | c.2159T>A p.L720H | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52287398, COSV99296605; called by muse, mutect2, varscan2
- CDH7 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV59889424; called by muse, mutect2
- CISD2 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs753403300, COSV56765656; called by muse, mutect2
- CLIP4 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 32/562 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV60750567; called by muse, mutect2
- CNTN5 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs199796384, COSV54331157, COSV99675626; called by muse, mutect2, varscan2
- CNTNAP2 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs149576292, COSV62141126; called by muse, mutect2, varscan2
- COL1A1 | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs1302873785, COSV56807235; called by muse, mutect2, varscan2
- COL3A1 | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV58592866; called by muse, mutect2
- COLEC11 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1360887774, COSV52595288; called by muse, mutect2, varscan2
- CPLX4 | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 172/706 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs766829811, COSV55314157; called by muse, mutect2, varscan2
- CR1L | c.486del p.T163Pfs*21 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as rs765293717; called by mutect2, pindel
- CSTL1 | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55677714, COSV55678590; called by muse, mutect2
- DACH2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs757022695, COSV64176887; called by muse, mutect2, varscan2
- DDR1 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV61322661; called by muse, mutect2, varscan2
- DHRS9 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV59140745; called by muse, mutect2, varscan2
- DHX15 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 89/319 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61028214; called by muse, mutect2, varscan2
- DHX40 | c.1675A>G p.I559V | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52068837; called by muse, mutect2, varscan2
- DIS3 | c.2333C>A p.P778H | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66707160; called by muse, mutect2, varscan2
- DLG5 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64946337; called by muse, mutect2
- DNAH7 | c.3988G>T p.A1330S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56774156; called by muse, mutect2, varscan2
- DOCK1 | c.362T>C p.M121T | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV54748152; called by muse, mutect2, varscan2
- DOK3 | c.44A>G p.Q15R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV57253337; called by muse, mutect2, varscan2
- DST | c.5879C>T p.S1960F | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV55026114; called by muse, mutect2, varscan2
- ELN | c.2041G>A p.G681R (on ENST00000320399 / NM_001278939.1; = p.G648R on NM_000501.4) | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as rs782184500, COSV52706785; called by muse, mutect2, varscan2
- EMCN | c.204A>T p.E68D | Missense Mutation (SNP) | VAF 118/427 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV56461237; called by muse, mutect2, varscan2
- ERBB4 | c.2744C>G p.T915S | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV61495364, COSV61500983, COSV61503340; called by muse, mutect2, varscan2
- EVI5 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64828564; called by muse, mutect2
- EVI5L | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54484182; called by muse, mutect2
- FAM20A | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56837437; called by muse, mutect2
- FBXO11 | c.398G>C p.R133P (on ENST00000403359 / NM_001190274.2; = p.R49P on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as COSV57023071; called by muse, mutect2, varscan2
- FBXO24 | c.527G>A p.R176H (on ENST00000241071 / NM_033506.3; = p.R214H on NM_012172.5) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs768402143, COSV53827718; called by muse, mutect2, varscan2
- FBXO42 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286504246, COSV65046281; called by muse, mutect2, varscan2
- FIBIN | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.349); catalogued as COSV59413171; called by muse, mutect2, varscan2
- FZD2 | c.298T>C p.C100R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59529578; called by muse, mutect2, varscan2
- GABRA2 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62916778; called by muse, mutect2
- GABRP | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 98/341 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336167569, COSV54662954; called by muse, mutect2, varscan2
- GALNT3 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as rs763726940, COSV67061814; called by muse, mutect2, varscan2
- GAPVD1 | c.2308G>A p.G770S | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52925054; called by muse, mutect2, varscan2
- GGN | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1474770509, COSV53057252; called by muse, mutect2, varscan2
- GJD2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV51747793; called by muse, mutect2, varscan2
- GLB1L2 | c.1353del p.Q452Rfs*4 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as rs1565443113, COSV60278204; called by mutect2, pindel, varscan2
- GLRA1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.862); catalogued as rs776477331, COSV51019177; called by muse, mutect2, varscan2
- GPRASP2 | c.1200G>C p.E400D | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); catalogued as COSV59990510, COSV59991956; called by muse, mutect2, varscan2
- GTF2E2 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 33/579 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs776412409, COSV63478747; called by muse, mutect2
- HADHB | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58547278; called by muse, mutect2, varscan2
- HCN4 | c.3536del p.P1179Lfs*2 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV56083014; called by mutect2, varscan2
- HECW2 | c.4493A>G p.Q1498R | Missense Mutation (SNP) | VAF 15/442 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53665999; called by muse, mutect2
- HEPACAM2 | c.1088T>C p.I363T (on ENST00000394468 / NM_001039372.4; = p.I351T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59061863; called by muse, mutect2
- HIP1R | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1417811350, COSV53442997; called by muse, mutect2, varscan2
- HIPK1 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61249142, COSV61249620; called by muse, mutect2, varscan2
- HMBOX1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 57/416 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV55070076; called by muse, mutect2, varscan2
- HNRNPH1 | c.582T>G p.H194Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as COSV61487293; called by muse, mutect2, varscan2
- HSPB8 | c.266dup p.P90Tfs*37 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs773017653; called by mutect2, varscan2
- IFT140 | c.3251C>A p.A1084E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757199524, COSV54152205, COSV54153732; called by muse, mutect2, varscan2
- IFT80 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 131/456 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58449831; called by muse, varscan2
- IGFN1 | c.1528C>T p.H510Y (on ENST00000295591 / NM_001367841.1; = p.H2967Y on NM_001164586.2) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV55177749; called by muse, mutect2, varscan2
- IGHD | c.640dup p.V215Rfs*70 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs1566803405; called by mutect2, pindel
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 74/262 reads (28%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- ITGAV | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 101/429 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV53715582; called by muse, mutect2, varscan2
- ITPR1 | c.3374C>A p.S1125Y (on ENST00000354582; = p.S1110Y on NM_002222.7) | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.632); catalogued as COSV100233683, COSV56991669; called by muse, mutect2, varscan2
- ITSN2 | c.4559G>T p.R1520L | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61950547; called by muse, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 26/167 reads (16%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KAT6B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs568525923, COSV54741444; called by muse, mutect2, varscan2
- KDM4D | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV58634199; called by muse, mutect2
- KIAA0100 | c.2018del p.P673Qfs*20 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1567659088, COSV66496054; called by mutect2, pindel, varscan2
- KIF13A | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs565377483, COSV52457772; called by muse, mutect2, varscan2
- KIF14 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 100/333 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs116130210, COSV100950946; called by muse, mutect2, varscan2
- KLHL32 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs140246562, COSV65111774; called by muse, mutect2, varscan2
- KRT81 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59810585; called by muse, mutect2, varscan2
- LAMA2 | c.7749G>T p.Q2583H | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV70351685; called by muse, mutect2, varscan2
- LAPTM4A | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 127/449 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51533193; called by muse, mutect2, varscan2
- LDHB | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs760127821, COSV63365181; called by muse, mutect2, varscan2
- LINGO4 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV59092803, COSV59094200; called by muse, mutect2, varscan2
- LONP2 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53523992; called by muse, mutect2
- LUC7L3 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV53588175; called by muse, mutect2, varscan2
- MAGEB6 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 128/478 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV66871893, COSV66872236; called by muse, mutect2, varscan2
- MAGEC3 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as COSV68923935; called by muse, mutect2
- MAP3K5 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV62890352; called by muse, mutect2
- MAS1L | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV65809215; called by muse, mutect2
- MCAT | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as rs371131732; called by muse, mutect2, varscan2
- MCPH1 | c.1402dup p.T468Nfs*5 | Frame Shift Ins (INS) | VAF 48/126 reads (38%) | catalogued as rs768835889; called by mutect2, varscan2
- MEI1 | c.1537A>G p.R513G | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55904892; called by muse, mutect2, varscan2
- METAP1 | c.1000G>C p.G334R | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV56444865; called by muse, mutect2, varscan2
- MFSD4A | c.231-1G>A p.X77_splice | Splice Site (SNP) | VAF 29/87 reads (33%) | catalogued as COSV65656752; called by muse, mutect2, varscan2
- MFSD6 | c.1931G>A p.S644N | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.585); catalogued as COSV55623819; called by muse, mutect2, varscan2
- MLH3 | c.2656_2657del p.E886Nfs*11 | Frame Shift Del (DEL) | VAF 36/127 reads (28%) | catalogued as rs747672055; called by pindel, varscan2
- MMEL1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56523520; called by muse, mutect2, varscan2
- MMS22L | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs778194658, COSV51519763, COSV51523249; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3292C>T p.Q1098* | Nonsense Mutation (SNP) | VAF 47/168 reads (28%) | catalogued as rs202155525, COSV56621667; called by muse, mutect2, varscan2
- MTRF1L | c.447A>G p.I149M | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV65873743; called by muse, mutect2, varscan2
- MTSS1 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as rs1195375883, COSV61498498; called by muse, mutect2, varscan2
- MUC6 | c.5006C>G p.P1669R | Missense Mutation (SNP) | VAF 64/1276 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV70144957, COSV70149888; called by muse, mutect2
- MVB12A | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV57679240; called by muse, mutect2, varscan2
- MYF5 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57355728; called by muse, mutect2, varscan2
- MYLK | c.4870A>T p.T1624S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV60615090; called by muse, mutect2, varscan2
- MYO1H | c.2389C>T p.R797W | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777322229, COSV100183859; called by muse, mutect2
- NARS1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 194/717 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs200649043, COSV56877530; called by muse, mutect2, varscan2
- NCF4 | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV50622975; called by muse, mutect2, varscan2
- NEB | c.1466A>C p.K489T | Missense Mutation (SNP) | VAF 22/584 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51434697; called by muse, mutect2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 140/538 reads (26%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NOTCH2 | c.5696C>T p.A1899V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56697266; called by muse, mutect2, varscan2
- NRDC | c.1463T>G p.F488C | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61406320; called by muse, mutect2, varscan2
- NUFIP1 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 20/734 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64791612; called by muse, mutect2
- NUFIP1 | c.494dup p.K166Efs*12 | Frame Shift Ins (INS) | VAF 94/398 reads (24%) | catalogued as rs770344882; called by mutect2, varscan2
- NUTM2F | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV53558691; called by muse, mutect2, varscan2
- OR10G2 | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV73390423; called by muse, mutect2
- OR10Q1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.191); catalogued as rs1306805450, COSV57469953; called by muse, mutect2, varscan2
- OR10V1 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55699468; called by muse, mutect2, varscan2
- OR4K13 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59860025; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 210/786 reads (27%) | catalogued as rs751106039; called by mutect2, varscan2
- P4HA2 | c.1308T>C p.N436= | Splice Region (SNP) | VAF 95/287 reads (33%) | catalogued as COSV51327673; called by muse, mutect2, varscan2
- PARD3 | c.1944A>T p.E648D | Missense Mutation (SNP) | VAF 139/502 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60754747; called by muse, mutect2, varscan2
- PARP11 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 21/458 reads (5%) | catalogued as rs375575295, COSV57394330; called by muse, mutect2
- PAX5 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.414); catalogued as rs750525788, COSV63904944, COSV63909765; called by muse, mutect2, varscan2
- PAX5 | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV100814653, COSV63909770; called by muse, mutect2, varscan2
- PCDHA11 | c.1982C>T p.T661M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as rs1330055406, COSV56523963; called by muse, mutect2, varscan2
- PCDHB8 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV50790751; called by muse, mutect2, varscan2
- PCNX3 | c.5291C>T p.A1764V | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.262); catalogued as rs370852890; called by muse, mutect2
- PCSK7 | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.818); catalogued as COSV58008357; called by mutect2, varscan2
- PDZD2 | c.3322del p.Q1108Sfs*17 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | catalogued as rs1212611383; called by mutect2, pindel, varscan2
- PEAK1 | c.4570C>T p.L1524F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56939400; called by muse, mutect2, varscan2
- PER3 | c.2382G>T p.Q794H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); catalogued as COSV62706803; called by muse, mutect2, varscan2
- PGR | c.2311G>A p.V771I | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1186005749, COSV54805557; called by muse, mutect2
- PKLR | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM941164, COSV61361826; called by muse, mutect2, varscan2
- PKM | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs772885059, COSV58790097; called by muse, mutect2, varscan2
- PLAT | c.1021C>A p.L341M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV54276807; called by muse, mutect2, varscan2
- PLCB3 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.36); catalogued as rs758823609, COSV54185829; called by muse, mutect2, varscan2
- PLCE1 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV53360118; called by muse, mutect2, varscan2
- PLCL2 | c.1193G>A p.G398D (on ENST00000615277 / NM_001144382.2; = p.G272D on NM_015184.5) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67623462; called by muse, mutect2, varscan2
- PNLIPRP2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782705930, COSV53943140; called by muse, mutect2, varscan2
- POGLUT1 | c.1172A>G p.E391G | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55157463; called by muse, mutect2
- PORCN | c.934T>C p.W312R (on ENST00000326194 / NM_203475.3; = p.W301R on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58226647; called by muse, mutect2, varscan2
- PPM1J | c.1487T>C p.I496T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53518567; called by muse, mutect2, varscan2
- PPP1R16B | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV55380239; called by muse, mutect2, varscan2
- PPP1R3A | c.2219C>T p.T740I | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV52886961; called by muse, varscan2
- PPP1R3F | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs782769164, COSV50019286; called by muse, mutect2, varscan2
- PRAMEF5 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1489961909; called by muse, mutect2, varscan2
- PRPF4 | c.143G>T p.G48V (on ENST00000374198 / NM_001322267.2; = p.G49V on NM_004697.5) | Missense Mutation (SNP) | VAF 17/469 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65253045; called by muse, mutect2
- PRUNE2 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765205658, COSV65028421, COSV65028915; called by muse, mutect2, varscan2
- PTPRB | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.075); catalogued as COSV51738444; called by muse, mutect2, varscan2
- RAB3IL1 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV57118244; called by muse, mutect2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 61/232 reads (26%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RBM14 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV59559822; called by muse, mutect2, varscan2
- RBM22 | c.92A>C p.N31T | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52272451; called by muse, mutect2, varscan2
- REC114 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.046); catalogued as COSV58521703; called by muse, mutect2
- RELL1 | c.507del p.T170Rfs*34 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | catalogued as COSV58455457; called by mutect2, pindel, varscan2
- RFX4 | c.504T>A p.Y168* (on ENST00000392842 / NM_213594.3; = p.Y74* on NM_032491.6) | Nonsense Mutation (SNP) | VAF 21/350 reads (6%) | catalogued as COSV57577900; called by muse, mutect2
- RHOXF2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.125); catalogued as rs782319401, COSV65047916; called by muse, varscan2
- RIPOR1 | c.1315C>A p.P439T (on ENST00000379312 / NM_001193522.2; = p.P435T on NM_024519.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV50235823; called by muse, mutect2, varscan2
- RUSC1 | c.1873C>A p.L625I (on ENST00000368352 / NM_001105203.2; = p.L156I on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); catalogued as rs977391581, COSV52741267; called by muse, mutect2, varscan2
- RYR3 | c.12833C>T p.S4278L (on ENST00000389232; = p.S4279L on NM_001036.6) | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.733); catalogued as COSV66799801; called by muse, mutect2
- SASS6 | c.1355C>A p.A452D | Missense Mutation (SNP) | VAF 44/406 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as COSV54928987; called by muse, mutect2, varscan2
- SCN5A | c.4009G>A p.V1337I (on ENST00000333535 / NM_198056.3; = p.V1336I on NM_000335.5) | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61131585; called by muse, mutect2, varscan2
- SEMA7A | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs771532027, COSV56091251, COSV56092697; called by mutect2, varscan2
- SETDB1 | c.2849del p.P950Qfs*16 | Frame Shift Del (DEL) | VAF 112/417 reads (27%) | catalogued as rs1220025296; called by mutect2, pindel, varscan2
- SFXN5 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV55588375; called by muse, mutect2, varscan2
- SH3KBP1 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.282); catalogued as COSV65643081; called by muse, mutect2, varscan2
- SIK3 | c.3049C>T p.P1017S (on ENST00000445177 / NM_001366686.2; = p.P975S on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52618601; called by muse, mutect2, varscan2
- SLC20A2 | c.1605G>A p.W535* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV60605067; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 49/187 reads (26%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC5A3 | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV62971460; called by muse, mutect2, varscan2
- SLC7A4 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs746470718, COSV60384923; called by muse, mutect2, varscan2
- SLU7 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 196/681 reads (29%) | catalogued as COSV51788985, COSV51791100; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 88/268 reads (33%) | catalogued as rs763364024; called by mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | catalogued as rs766085867, COSV100391091; called by mutect2, varscan2
- SNX12 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1048883139, COSV52146027; called by muse, mutect2, varscan2
- SORBS2 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV53006861; called by muse, mutect2, varscan2
- SPEM2 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs543678181, COSV61604253; called by muse, mutect2, varscan2
- SPIN2B | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 192/729 reads (26%) | catalogued as COSV52069085; called by muse, mutect2, varscan2
- SRRM2 | c.5863C>T p.R1955C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs975871788, COSV57070177; called by muse, mutect2, varscan2
- SRSF11 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV63937383; called by muse, mutect2, varscan2
- STAT6 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1171661454, COSV55672491; called by muse, mutect2, varscan2
- STK33 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV59405113; called by muse, mutect2, varscan2
- SYNE1 | c.19693-1G>T p.X6565_splice (on ENST00000367255 / NM_182961.4; = p.X6494_splice on NM_033071.3) | Splice Site (SNP) | VAF 8/164 reads (5%) | catalogued as COSV55033994; called by muse, mutect2
- TAB2 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 97/376 reads (26%) | catalogued as COSV53853722; called by muse, mutect2, varscan2
- TADA1 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.467); catalogued as COSV63310410; called by muse, mutect2, varscan2
- TAF1 | c.2467C>T p.R823W (on ENST00000373790 / NM_138923.4; = p.R844W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111149; called by muse, mutect2, varscan2
- TBXAS1 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54949312; called by muse, mutect2, varscan2
- TDRD6 | c.4671G>T p.Q1557H | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs1228298305, COSV60176875; called by muse, mutect2, varscan2
- TDRD6 | c.5569C>T p.Q1857* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV60176881; called by muse, mutect2, varscan2
- TENT5C | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.984); catalogued as rs538766512, COSV65616490; called by muse, mutect2, varscan2
- TMEM215 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV61363293; called by muse, mutect2, varscan2
- TMEM61 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as COSV64873743; called by muse, mutect2, varscan2
- TMEM67 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 128/424 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.355); catalogued as rs748441313, COSV60041966; called by muse, varscan2
- TPRKB | c.74del p.N25Mfs*5 | Frame Shift Del (DEL) | VAF 74/303 reads (24%) | catalogued as rs745369963; called by mutect2, pindel, varscan2
- TRIM60 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764622764, COSV61970927; called by muse, mutect2, varscan2
- TRMT10A | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as COSV56745572; called by muse, mutect2, varscan2
- TRPA1 | c.2592G>T p.E864D | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.686); catalogued as COSV100084901, COSV51567133; called by muse, mutect2, varscan2
- TTC3 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs538903036, COSV61293258; called by muse, mutect2, varscan2
- TTC3 | c.5995C>T p.R1999C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1305077584, COSV61285704; called by muse, mutect2, varscan2
- TTC7B | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs760210286, COSV60634742; called by muse, mutect2, varscan2
- TUB | c.263C>T p.A88V (on ENST00000299506 / NM_177972.3; = p.A143V on NM_003320.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.432); catalogued as rs775392476, COSV55108966; called by muse, mutect2, varscan2
- TUBA1A | c.1066A>T p.N356Y | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55498286; called by muse, mutect2, varscan2
- TUBA1C | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV56511038; called by muse, mutect2, varscan2
- UBR5 | c.6928C>T p.P2310S | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55293207; called by muse, mutect2, varscan2
- UBR7 | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50150399; called by muse, mutect2
- UPP1 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57978037; called by muse, mutect2
- USP26 | c.1461dup p.G488Wfs*6 | Frame Shift Ins (INS) | VAF 36/141 reads (26%) | catalogued as rs761320003; called by mutect2, varscan2
- USP31 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54854381; called by muse, mutect2, varscan2
- WRAP53 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.556); catalogued as COSV56833037; called by muse, mutect2, varscan2
- WRN | c.2834A>G p.H945R | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53303367; called by muse, mutect2
- XG | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV66985368; called by muse, mutect2, varscan2
- ZFHX3 | c.2096del p.G699Afs*125 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs753977275, COSV51729347; called by mutect2, varscan2
- ZFYVE21 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52453782; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2541_2543del p.I848del | In Frame Del (DEL) | VAF 59/212 reads (28%) | catalogued as rs752022614; called by pindel, varscan2
- ZMYM3 | c.1786A>G p.S596G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV58739204; called by muse, mutect2, varscan2
- ZNF433 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV61399818; called by muse, mutect2
- ZNF436 | c.409T>A p.Y137N | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV58358955; called by muse, mutect2, varscan2
- ZNF649 | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56816922; called by muse, mutect2, varscan2
- ZNF687 | c.2611del p.R871Gfs*29 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs1557773056, COSV55019646; called by mutect2, pindel, varscan2
- ZXDA | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1345795692, COSV62388303; called by muse, mutect2, varscan2
- ADGRB3 | c.*5del | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- AFAP1L1 | c.368del p.P123Lfs*49 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- AGO1 | c.1043_1045dup p.Q348dup | In Frame Ins (INS) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD49 | c.216del p.D73Tfs*29 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 61/216 reads (28%) | called by mutect2, varscan2
- ARMC2 | c.1012dup p.I338Nfs*6 | Frame Shift Ins (INS) | VAF 78/279 reads (28%) | called by mutect2, pindel, varscan2
- BRPF3 | c.3585del p.H1197Tfs*56 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- BTBD16 | c.906del p.F302Lfs*15 | Frame Shift Del (DEL) | VAF 99/492 reads (20%) | called by mutect2, pindel, varscan2
- C9orf72 | c.672_682del p.S225Afs*11 | Frame Shift Del (DEL) | VAF 46/195 reads (24%) | called by mutect2, pindel, varscan2
- CCDC85A | c.1038dup p.S347Efs*25 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- CHCHD6 | c.137del p.P46Lfs*15 | Frame Shift Del (DEL) | VAF 34/156 reads (22%) | called by mutect2, pindel, varscan2
- DCT | c.1176dup p.V393Cfs*8 | Frame Shift Ins (INS) | VAF 43/167 reads (26%) | called by mutect2, pindel, varscan2
- DHRS7 | c.642del p.F214Lfs*14 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by pindel, varscan2
- ELF3 | c.764_770del p.K255Tfs*37 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 135/511 reads (26%) | called by mutect2, pindel, varscan2
- FAT2 | c.12688del p.L4230Wfs*22 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- GALNT18 | c.1360del p.L454Wfs*8 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- GPR179 | c.2924dup p.A976Cfs*72 (on ENST00000621958; = p.A975Cfs*72 on NM_001004334.4) | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- IFNGR2 | c.546del p.G183Efs*20 | Frame Shift Del (DEL) | VAF 50/206 reads (24%) | called by mutect2, pindel, varscan2
- IGHG3 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PCDHA6 | c.1031del p.N344Mfs*7 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, varscan2
- PIGZ | c.1639del p.H547Ifs*2 | Frame Shift Del (DEL) | VAF 41/158 reads (26%) | called by mutect2, pindel, varscan2
- POGLUT2 | c.731del p.K244Rfs*23 | Frame Shift Del (DEL) | VAF 32/111 reads (29%) | called by mutect2, pindel, varscan2
- RAE1 | c.1052del p.N351Ifs*12 | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | called by mutect2, varscan2
- RFX5 | c.56del p.P19Qfs*28 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- SIMC1 | c.522_524dup p.R174dup (on ENST00000443967 / NM_001308196.1; = p.R193dup on NM_001308195.2) | In Frame Ins (INS) | VAF 63/240 reads (26%) | called by mutect2, pindel, varscan2
- SLC22A4 | c.717del p.F239Lfs*25 | Frame Shift Del (DEL) | VAF 75/256 reads (29%) | called by mutect2, pindel, varscan2
- SMARCAD1 | c.2199dup p.K734Qfs*6 | Frame Shift Ins (INS) | VAF 72/233 reads (31%) | called by mutect2, pindel, varscan2
- TBC1D32 | c.2240del p.K747Sfs*9 | Frame Shift Del (DEL) | VAF 38/369 reads (10%) | called by mutect2, pindel, varscan2
- TBC1D5 | c.1698del p.F566Lfs*23 | Frame Shift Del (DEL) | VAF 81/273 reads (30%) | called by mutect2, pindel, varscan2
- TMEM135 | c.1007dup p.L336Ffs*10 | Frame Shift Ins (INS) | VAF 168/640 reads (26%) | called by mutect2, pindel, varscan2
- ZFP69 | c.125_127del p.E42del | In Frame Del (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- ZNF185 | c.1591_1592del p.S531Lfs*22 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by pindel, varscan2
- AKAP1 | c.60C>T p.L20= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs867529780, COSV100027684, COSV58471247; called by muse, mutect2, varscan2
- ALPK1 | c.2460C>A p.S820= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV51588049; called by muse, mutect2, varscan2
- ANGPT1 | c.855C>T p.D285= | Silent (SNP) | VAF 22/538 reads (4%) | catalogued as COSV52447419; called by muse, mutect2
- BACE2 | c.624A>C p.S208= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as COSV57741253; called by muse, mutect2, varscan2
- BMP2 | c.25C>T p.L9= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV66578586; called by muse, mutect2, varscan2
- CCER1 | c.729C>A p.T243= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs750837284, COSV62647694; called by muse, mutect2, varscan2
- CDKL3 | c.1221C>T p.N407= | Silent (SNP) | VAF 10/332 reads (3%) | catalogued as COSV54743114; called by muse, mutect2
- CELF2 | c.438C>T p.N146= (on ENST00000416382 / NM_001025077.3; = p.N153= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs555035980, COSV59978296; called by muse, mutect2, varscan2
- CSMD3 | c.8064C>T p.R2688= (on ENST00000297405 / NM_001363185.1; = p.R2584= on NM_052900.3) | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as COSV52241008; called by muse, mutect2, varscan2
- EP400 | c.5280G>A p.E1760= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV57778230; called by muse, mutect2, varscan2
- EVPL | c.2463T>C p.Y821= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV56913290; called by muse, mutect2, varscan2
- GAB1 | c.447C>A p.T149= | Silent (SNP) | VAF 114/438 reads (26%) | catalogued as rs1560766444, COSV53758511; called by muse, mutect2, varscan2
- GCC1 | c.1839T>C p.S613= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV58463126; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2373G>A p.L791= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs201410756, COSV63100573; called by mutect2, varscan2
- HASPIN | c.1788C>T p.D596= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV53990730; called by muse, mutect2, varscan2
- HSD17B7 | c.165T>C p.A55= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV54419022; called by muse, mutect2, varscan2
- HTR2C | c.375T>C p.Y125= | Silent (SNP) | VAF 224/716 reads (31%) | catalogued as COSV52218121; called by muse, mutect2, varscan2
- IFNA14 | c.558G>A p.R186= | Silent (SNP) | VAF 152/528 reads (29%) | catalogued as rs751186366, COSV66516276; called by muse, mutect2, varscan2
- ITGA11 | c.861C>T p.S287= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as rs377301043; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMB2 | c.3834G>A p.Q1278= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV59735463; called by muse, mutect2, varscan2
- LARS1 | c.1881G>A p.P627= (on ENST00000394434 / NM_020117.11; = p.P600= on NM_016460.3) | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs762428409, COSV50972972; called by muse, mutect2, varscan2
- LMX1A | c.801C>A p.T267= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs759281992, COSV54224237; called by muse, mutect2, varscan2
- MAGEA3 | c.663C>T p.I221= | Silent (SNP) | VAF 78/262 reads (30%) | catalogued as rs1556826745, COSV100939002, COSV100939087, COSV64756320; called by muse, mutect2, varscan2
- MAST1 | c.3615G>A p.S1205= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52250312, COSV99262282; called by muse, mutect2, varscan2
- METTL9 | c.876A>G p.R292= | Silent (SNP) | VAF 88/264 reads (33%) | catalogued as COSV51679694; called by muse, mutect2, varscan2
- MTARC2 | c.732C>T p.G244= | Silent (SNP) | VAF 86/428 reads (20%) | catalogued as COSV63765977; called by muse, mutect2, varscan2
- MUC17 | c.1533T>C p.T511= | Silent (SNP) | VAF 34/484 reads (7%) | catalogued as COSV60295305; called by muse, mutect2
- MYOF | c.3345G>A p.K1115= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as COSV63707120; called by muse, mutect2, varscan2
- NAA35 | c.1419C>G p.T473= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as COSV64485682; called by muse, mutect2, varscan2
- ODF4 | c.351C>T p.P117= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs750499239, COSV100071919; called by muse, mutect2
- OR10A5 | c.939A>G p.R313= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV55054933; called by muse, mutect2, varscan2
- PADI2 | c.1485G>A p.S495= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs779905920, COSV64945997; called by muse, mutect2, varscan2
- PCDH10 | c.759C>T p.P253= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs562154592, COSV52098781; called by muse, mutect2, varscan2
- PCDHA13 | c.1734C>T p.S578= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56490478; called by muse, mutect2, varscan2
- PCNA | c.54A>G p.A18= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs773328092, COSV64770650; called by muse, mutect2, varscan2
- PGBD2 | c.1206C>T p.V402= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as rs771012383, COSV61400616, COSV61400954; called by muse, mutect2, varscan2
- PKD1L1 | c.6429C>T p.T2143= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs761120485, COSV56970637; called by muse, mutect2, varscan2
- PLSCR5 | c.429C>T p.C143= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as rs375086007, COSV71649123; called by muse, mutect2, varscan2
- PNN | c.1836T>C p.S612= | Silent (SNP) | VAF 102/334 reads (31%) | catalogued as COSV53767372; called by muse, mutect2, varscan2
- POLB | c.45C>T p.I15= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs755089897, COSV55347567; called by muse, mutect2, varscan2
- POLD3 | c.444C>A p.S148= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as COSV55244089, COSV99738008; called by muse, mutect2, varscan2
- PORCN | c.978C>T p.T326= (on ENST00000326194 / NM_203475.3; = p.T315= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as COSV58226655; called by muse, mutect2, varscan2
- POU6F2 | c.867G>A p.T289= | Silent (SNP) | VAF 52/164 reads (32%) | catalogued as rs774648361, COSV68873320; called by muse, mutect2, varscan2
- PPRC1 | c.744A>G p.E248= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs1186573755, COSV53386992; called by muse, mutect2, varscan2
- REEP1 | c.259C>T p.L87= | Silent (SNP) | VAF 117/378 reads (31%) | catalogued as COSV51257936; called by muse, mutect2, varscan2
- RHOBTB3 | c.435C>T p.C145= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV66102550; called by muse, mutect2
- RNF103 | c.1455C>T p.D485= | Silent (SNP) | VAF 60/227 reads (26%) | catalogued as rs147769955; called by muse, mutect2, varscan2
- RNF113A | c.384C>T p.R128= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV65097587; called by muse, mutect2, varscan2
- RSPH10B2 | c.2496A>G p.T832= | Silent (SNP) | VAF 117/454 reads (26%) | catalogued as COSV51870331; called by muse, mutect2, varscan2
- SEC11C | c.447C>T p.D149= | Silent (SNP) | VAF 88/340 reads (26%) | catalogued as rs148883849; called by muse, mutect2, varscan2
- SEC24D | c.1773G>A p.G591= | Silent (SNP) | VAF 89/347 reads (26%) | catalogued as COSV54882004; called by muse, mutect2, varscan2
- SF3A1 | c.357G>A p.Q119= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV53170033; called by muse, mutect2, varscan2
- SFPQ | c.111C>T p.G37= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV61758948; called by muse, mutect2, varscan2
- SIMC1 | c.759G>A p.R253= (on ENST00000443967 / NM_001308196.1; = p.R272= on NM_001308195.2) | Silent (SNP) | VAF 133/401 reads (33%) | catalogued as rs1172972829, COSV57904914; called by muse, mutect2, varscan2
- SIX2 | c.432G>A p.A144= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs747117944, COSV57391541; called by muse, mutect2, varscan2
- SLC11A1 | c.366C>T p.G122= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs755184553, COSV51918145; called by muse, mutect2, varscan2
- SLC25A24 | c.735A>G p.G245= | Silent (SNP) | VAF 109/391 reads (28%) | catalogued as COSV51448963; called by muse, mutect2, varscan2
- SLC7A14 | c.1680G>A p.A560= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as rs898982859, COSV51585777; called by muse, mutect2, varscan2
- SMARCA4 | c.1683G>T p.V561= | Silent (SNP) | VAF 57/161 reads (35%) | catalogued as COSV60801798; called by muse, mutect2, varscan2
- SOX30 | c.1626C>T p.S542= | Silent (SNP) | VAF 59/170 reads (35%) | catalogued as rs138475659; called by muse, mutect2, varscan2
- STAP2 | c.684C>T p.A228= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV55697585; called by muse, mutect2, varscan2
- STON2 | c.1683C>T p.V561= (on ENST00000649389 / NM_001366849.2; = p.V504= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as COSV50848070; called by muse, mutect2
- TENT4A | c.1551G>A p.P517= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs755913044, COSV50097075; called by muse, mutect2, varscan2
- TEX14 | c.582G>A p.L194= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as rs1222082876, COSV53621050; called by muse, mutect2, varscan2
- THOC2 | c.3747T>C p.P1249= | Silent (SNP) | VAF 28/460 reads (6%) | catalogued as COSV55550456; called by muse, mutect2
- TIAM1 | c.3438C>T p.C1146= | Silent (SNP) | VAF 61/231 reads (26%) | catalogued as rs141775592; called by muse, mutect2, varscan2
- TPM4 | c.81G>A p.A27= | Silent (SNP) | VAF 62/220 reads (28%) | catalogued as COSV61209718; called by muse, mutect2, varscan2
- TRIM37 | c.2784C>T p.F928= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV51886140; called by muse, mutect2
- TTC39A | c.24C>T p.D8= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV52959804; called by muse, mutect2, varscan2
- UGT2B7 | c.228T>C p.I76= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV59444372; called by muse, mutect2, varscan2
- VAV1 | c.1107C>T p.C369= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV58387233; called by muse, varscan2
- CDC37P1 | n.955C>T | RNA (SNP) | VAF 4/6 reads (67%) | catalogued as rs763270808, COSV73722421; called by mutect2, varscan2
- TRIM8 | c.*531C>G | 3'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs1380083291, COSV56661266; called by muse, mutect2, varscan2
